Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1O7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1O7-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

adenocarcinoma, endometrioid, Nos 8380/3

Site: endometrium C54.1 2/24/11 ju

Surgical Pathology

UUID:37C25226-AD56-487E-969B-1538E6E00ASD

SLIDE DISPOSITION:

DIAGNOSIS:

Uterus, bilateral ovaries, and fallopian tubes;
hysterectomy and
bilateral salpingo-oophorectomy: FIGO grade 1 (of 3)
endometrial
adenocarcinoma, endometrioid type, is identified forming a
mass (2.8
x 1.5 x 0.9 cm), involving the fundus. The tumor invades
0.1 cm
into the myometrium (total wall thickness 2.0 cm). The
tumor does
not involve the endocervix. Lymphovascular space invasion
is not
identified. The margins are negative for tumor. There
are multiple
(2 subserosal, each 0.1 cm in greatest dimension; 5
intramural,
ranging in size from 0.4 cm to 0.7 cm in greatest
dimension)
leiomyomata in the myometrium. The bilateral ovaries and
fallopian
tubes are not involved. The fallopian tubes show mild
hydrosalpinx
(right, 2.8 x 1.5 x 1.3 cm; left, 2.2 x 1.2 x 1.2 cm).

With available surgical material [AJCC pT1a] (7th edition,
2010).

This final pathology report is based on the
gross/macrosopic
examination and the frozen section histologic evaluation
of the
specimen(s). Hematoxylin and Eosin (H&E) permanent
sections are
reviewed to confirm these findings. Any substantive
changes
identified on permanent section review will be reflected
in a

[page 2 of 2]
revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, left and right fallopian tubes and ovaries" is a 95.0 gram uterus with attached bilateral fallopian tubes and ovaries. The uterine serosa is smooth. There is a 2.8 x 1.5 x 0.9 cm polypoid mass in the fundus of the endometrial cavity grossly invading 0.1 cm - 0.2 cm. The myometrial thickness is 2.0 cm. There are multiple (2 subserosal, each 0.1 cm in greatest dimension; 5 intramural, ranging in size from 0.4 cm to 0.7 cm in greatest dimension) leiomyomata in the myometrium. There is a 1.7 x 1.4 x 1.1 cm right ovary with a nodular outer surface and a solid cut surface with a 7.3 x 1.5 x 1.3 cm right fallopian tube which has hydrosalpinx (2.8 x 1.5 x 1.3 cm). There is a 1.6 x 1.1 x 0.9 cm left ovary with a nodular outer surface and a solid cut surface with an 8.3 x 1.2 x 1.2 cm left fallopian tube which has hydrosalpinx (2.2 x 1.2 x 1.2 cm). Representative sections are submitted.

Source: NCI Genomic Data Commons file 5cdf69de-fb38-4f19-8996-249297735959 (TCGA-D1-A1O7.37C25226-AD56-487E-969B-1538E6E00A5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).